Somatic mutation profile of tumor specimen TCGA-75-7030-01A (aliquot TCGA-75-7030-01A-11D-1945-08) from TCGA case TCGA-75-7030, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB.
Specimen TCGA-75-7030-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11453881-ef25-4187-af52-a687736c02f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-75-7030-10A (Blood Derived Normal), aliquot TCGA-75-7030-10A-01D-1946-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a05cc25a-f110-4410-8f60-ec64b8b848c3

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TG | c.7021G>A p.G2341S | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs898275076, COSV55094384; ClinVar: pathogenic; called by muse, mutect2
- CHRM3 | c.1592G>T p.W531L | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55104940, COSV99697990; called by muse, mutect2
- DAPP1 | c.320A>G p.K107R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.187); catalogued as COSV56453760; called by muse, mutect2
- FAT3 | c.12226G>A p.D4076N | Missense Mutation (SNP) | VAF 16/247 reads (6%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.517); catalogued as rs753130799, COSV53175009; called by muse, mutect2
- SCN8A | c.3583G>A p.V1195M | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61993246; called by muse, mutect2
- SYNCRIP | c.1141C>G p.R381G | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100784175, COSV100784264, COSV62289354; called by muse, mutect2
- IGKV1D-43 | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2
- UGT2B4 | c.966T>C p.N322= | Silent (SNP) | VAF 9/238 reads (4%) | catalogued as rs1170230992, COSV59320780; called by muse, mutect2
